Somatic mutation profile of tumor specimen TCGA-T2-A6X0-01A (aliquot TCGA-T2-A6X0-01A-11D-A34J-08) from TCGA case TCGA-T2-A6X0, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tonsil, NOS; Tumor grade: G2; Age at diagnosis: 49.6 years (18,114 days).
Specimen TCGA-T2-A6X0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b34d5c8d-1eeb-427b-ae76-94587e6f5475.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-T2-A6X0-10B (Blood Derived Normal), aliquot TCGA-T2-A6X0-10B-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/717a4dba-17c5-49f4-9532-b9d63010a4ba

The open-access MAF lists 64 somatic variants for this specimen: 46 protein-altering or splice-affecting, 18 silent.
By variant classification: Missense Mutation 40, Silent 18, Nonsense Mutation 5, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 44/92 reads (48%) | hotspot (GDC flag); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TRRAP | c.3127G>A p.A1043T | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.066); catalogued as rs1562945106, COSV62841115; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB8 | c.1450C>T p.R484C (on ENST00000297504 / NM_001282291.2; = p.R467C on NM_007188.5) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs561955380, COSV99874392; called by muse, mutect2, varscan2
- ADGRF1 | c.1679C>T p.T560M | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.025); catalogued as rs144411523, COSV51945449; called by muse, mutect2, varscan2
- ASXL3 | c.2555T>G p.I852S | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); catalogued as COSV99324890; called by muse, mutect2, varscan2
- CARNS1 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs368228836; called by muse, mutect2, varscan2
- CASKIN1 | c.4246G>A p.G1416S | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.999); catalogued as rs779937875, COSV100399520, COSV100399784; called by muse, varscan2
- CDH2 | c.1262G>A p.R421K | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV52287809, COSV52292857; called by muse, mutect2, varscan2
- CENPE | c.2487T>G p.F829L | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99477914; called by muse, mutect2, varscan2
- CHRD | c.1448G>A p.G483D | Missense Mutation (SNP) | VAF 68/426 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52606248, COSV99200426; called by muse, varscan2
- CIT | c.5771G>A p.R1924Q | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); catalogued as COSV99949595; called by muse, mutect2
- DNAJA1 | c.760C>T p.R254* | Nonsense Mutation (SNP) | VAF 9/55 reads (16%) | catalogued as COSV58309722; called by muse, mutect2, varscan2
- DOK6 | c.169C>A p.H57N | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.192); catalogued as COSV101234492, COSV66929801; called by muse, mutect2, varscan2
- EPHB1 | c.760A>G p.T254A | Missense Mutation (SNP) | VAF 24/384 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.18); catalogued as COSV101213168; called by muse, mutect2
- FAM135B | c.2915T>C p.V972A | Missense Mutation (SNP) | VAF 57/161 reads (35%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); catalogued as COSV99423920; called by muse, mutect2, varscan2
- FAT3 | c.10679C>A p.T3560N | Missense Mutation (SNP) | VAF 71/147 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99966083; called by muse, mutect2, varscan2
- GABRA2 | c.220G>A p.V74M | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV62912472; called by muse, mutect2, varscan2
- HNRNPM | c.1586T>C p.M529T | Missense Mutation (SNP) | VAF 53/111 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as COSV55311859; called by muse, mutect2, varscan2
- IARS2 | c.1681G>A p.G561S | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs746084166, COSV100228311; called by muse, mutect2, varscan2
- IQCN | c.3031G>C p.A1011P | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as COSV100828275; called by muse, mutect2, varscan2
- MAP2 | c.4556T>A p.V1519E | Missense Mutation (SNP) | VAF 53/145 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV99559907; called by muse, mutect2, varscan2
- MMP1 | c.1235C>A p.P412H | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100187969, COSV59509280; called by muse, mutect2, varscan2
- MYO1B | c.1389G>C p.E463D | Missense Mutation (SNP) | VAF 74/216 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV100269174; called by muse, mutect2, varscan2
- NOTCH3 | c.5452G>A p.A1818T | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.487); catalogued as COSV99657219; called by muse, mutect2, varscan2
- PCDH9 | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs902457317, COSV60573496, COSV60603010; called by muse, mutect2
- PDE10A | c.1121C>T p.T374M | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100605078; called by muse, mutect2, varscan2
- PHF19 | c.1466G>A p.R489Q | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs762411221, COSV65878701; called by muse, mutect2, varscan2
- PKD1L2 | c.1018C>T p.R340* | Nonsense Mutation (SNP) | VAF 26/77 reads (34%) | catalogued as rs758169798, COSV61416645; called by muse, mutect2, varscan2
- PNKP | c.1159G>A p.V387M | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs1480890100, COSV55589291; called by muse, mutect2, varscan2
- PTCH2 | c.3313G>A p.V1105M | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.081); catalogued as rs745450202, COSV100807990, COSV63400321; called by muse, mutect2, varscan2
- PYGM | c.2449A>G p.T817A | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.812); catalogued as COSV99377101; called by muse, mutect2, varscan2
- RPRD2 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); catalogued as rs782395575; called by muse, mutect2
- SCYL2 | c.2234C>G p.T745S | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100675000, COSV100675187; called by muse, mutect2, varscan2
- SMAD9 | c.58A>G p.R20G | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.285); catalogued as COSV100614709; called by muse, mutect2, varscan2
- SPATA31A1 | c.748G>A p.V250I | Missense Mutation (SNP) | VAF 42/268 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1296925874; called by muse, varscan2
- SPATA7 | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs753250204, COSV50416166; called by muse, mutect2, varscan2
- SRC | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.988); catalogued as COSV62441630; called by muse, varscan2
- TIMD4 | c.683C>T p.S228L | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV99192626; called by muse, mutect2, varscan2
- TP53TG5 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746467139, COSV101022342; called by muse, mutect2, varscan2
- TTN | c.20164G>T p.D6722Y (on ENST00000591111; = p.D5795Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | PolyPhen probably damaging (0.999); catalogued as COSV100612362; called by muse, mutect2, varscan2
- UBE3C | c.2752G>A p.A918T | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.796); catalogued as COSV100779951; called by muse, mutect2
- UCKL1 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 69/199 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756969918, COSV100700499; called by muse, mutect2, varscan2
- USH1G | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.27); catalogued as rs373170645, COSV58883884; called by muse, mutect2, varscan2
- VGLL3 | c.400C>T p.R134* | Nonsense Mutation (SNP) | VAF 37/113 reads (33%) | catalogued as COSV101051931; called by muse, mutect2, varscan2
- ZNF763 | c.226G>T p.E76* (on ENST00000358987 / NM_001367172.2; = p.E79* on NM_001012753.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 68/209 reads (33%) | catalogued as COSV59688968; called by muse, mutect2, varscan2
- ZBTB5 | c.1550_1552del p.F517del | In Frame Del (DEL) | VAF 11/36 reads (31%) | called by mutect2, pindel, varscan2
- ACTN1 | c.2304C>T p.P768= | Silent (SNP) | VAF 91/237 reads (38%) | catalogued as rs768216429, COSV51997037; called by muse, mutect2, varscan2
- CELSR1 | c.4080C>T p.C1360= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs781404334, COSV99418276; called by muse, mutect2, varscan2
- DLGAP4 | c.1470G>A p.A490= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs776836219, COSV100211228; called by muse, mutect2, varscan2
- FOXL2 | c.174G>A p.S58= | Silent (SNP) | VAF 25/165 reads (15%) | catalogued as rs747633105, COSV100374551; called by muse, mutect2, varscan2
- HOXB3 | c.762G>A p.S254= | Silent (SNP) | VAF 82/215 reads (38%) | catalogued as rs781526391, COSV57488079; called by muse, mutect2, varscan2
- KCNK10 | c.672G>A p.K224= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as COSV100068338, COSV56653302; called by muse, mutect2, varscan2
- KIAA1755 | c.2397G>A p.L799= | Silent (SNP) | VAF 36/102 reads (35%) | catalogued as rs769392337, COSV99642003; called by muse, mutect2, varscan2
- LRRK2 | c.480C>T p.F160= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as COSV100110165; called by muse, mutect2, varscan2
- MAPK12 | c.831G>A p.L277= | Silent (SNP) | VAF 33/109 reads (30%) | catalogued as COSV99299351; called by muse, mutect2, varscan2
- MUC17 | c.6645T>C p.P2215= | Silent (SNP) | VAF 25/672 reads (4%) | catalogued as rs763903791, COSV100073202; called by muse, mutect2
- MUC4 | c.13854C>T p.G4618= (on ENST00000463781 / NM_018406.7; = p.G382= on NM_004532.6) | Silent (SNP) | VAF 13/97 reads (13%) | catalogued as rs757755260, COSV100204659; called by muse, mutect2, varscan2
- NLRP8 | c.2097T>C p.F699= | Silent (SNP) | VAF 45/162 reads (28%) | catalogued as rs748368631, COSV99405277; called by muse, mutect2, varscan2
- RIC3 | c.930C>T p.D310= (on ENST00000309737 / NM_001206671.4; = p.D309= on NM_024557.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 57/141 reads (40%) | catalogued as rs745930827, COSV100111994; called by muse, mutect2, varscan2
- RSPH10B | c.423G>A p.P141= | Silent (SNP) | VAF 10/14 reads (71%) | catalogued as COSV100521300; called by mutect2, varscan2
- SLC6A9 | c.480C>T p.F160= (on ENST00000360584 / NM_201649.4; = p.F106= on NM_006934.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 52/82 reads (63%) | catalogued as rs140834307; called by muse, mutect2, varscan2
- SPTA1 | c.6621G>A p.Q2207= | Silent (SNP) | VAF 56/151 reads (37%) | catalogued as rs1206486118, COSV100934924; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TMEM165 | c.930G>A p.A310= | Silent (SNP) | VAF 38/134 reads (28%) | catalogued as rs368593849; called by muse, mutect2, varscan2
- VGLL4 | c.57C>T p.D19= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as rs368803680; called by muse, mutect2, varscan2
